Gene-level copy-number profile of tumor specimen TCGA-ZT-A8OM-01A from TCGA case TCGA-ZT-A8OM, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type A, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 73.7 years (26,923 days).
Specimen TCGA-ZT-A8OM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.e85141f5-3fcf-4b78-82c6-977d18a039dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZT-A8OM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/685a265c-58ef-40e8-9a22-1ad3637f6fb1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21; copy number 2: 59,795.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZT-A8OM-01A-11D-A427-01): tumor purity 0.96, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
